Surgical pathology report (de-identified scan), TCGA case TCGA-RC-A6M4, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Utah, specimen TCGA-RC-A6M4-01A (Primary Tumor).

[page 1 of 3]
SP Final Report

* Final Report *

Result Type: SP Final Report
Service Date: [REDACTED]
Result Status: Final
Result Title: Surg Path Final Report
Authored By: [REDACTED]
Electronically Signed By: [REDACTED]

* Final Report *

Diagnosis

1. "LIVER, SEGMENT SIX", (RESECTION):

- HEPATOCELLULAR CARCINOMA, MODERATELY DIFFERENTIATED, APPROXIMATELY 19.0 CENTIMETERS, MULTINODULAR TUMOR MASSES IDENTIFIED.
- CARCINOMA IS PRESENT AT INKED SURGICAL RESECTION MARGIN.
- NO EVIDENCE OF INTRAVASCULAR INVASION.
- NON-NEOPLASTIC LIVER PARENCHYMA SHOWING MILD PORTAL TRACT LYMPHOPLASMATIC INFILTRATE.
- SEE SYNOPTIC REPORT FOR TUMOR STAGE.

ICD-O-3

Carcinoma, hepatocellular ^{NOS}
8174/3

Site Liver C22.0

QW 7/24/13

2. "LIVER, LEFT LATERAL SEGMENT NODULE", (BIOPSY):

- HEPATOCELLULAR CARCINOMA.

Signature Line

I certify that I personally conducted the
diagnostic evaluation on the above specimens
and have rendered the above diagnosis(es):

[REDACTED]
electronic signature

Department of Pathology

For questions regarding this case, call

Clinical History

No history provided.

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
SP Final Report

* Final Report *

Microscopic Examination
Performed.

Submitting Physician
General Surgery

Comments
Immunohistochemical stains were performed at laboratories with appropriate controls. The tumor cells are positive for CEA(p) and CD10 with a canalicular pattern. The findings support the above diagnosis.

Gross Description

Two specimens are received, each of which is received labeled with the patient's name and medical record number.

Part one is received in formalin labeled "segment six lesion", and consists of a 1,600 gram, 19.5 x 15.0 x 10.5 cm unoriented, large, irregular, distorted, predominantly encapsulated mass with a focal probable research incision. The outer surface of the mass is gray-red to brown to yellow and is diffusely shaggy with numerous adhesions. A focal brown-yellow, irregular, and somewhat hemorrhagic margin of resection is identified. The noted areas of yellow, somewhat nodularity foci on the outer surface are present at the margin of resection. The margin of resection is inked black. Sectioning reveals the mass to be completely involved by a dusky red-tan to green, necrotic, soft to rubbery mass that extends to the inked margin of resection, as well as the surrounding capsule. There is a very minimal amount of uninvolved appearing liver parenchyma adjacent to the edge of the margin at one end. Representative sections are submitted as follows: 1A-1D - mass to inked margin; 1E-1F - mass to surrounding capsule; 1G-1H - random mass.

Part two is received in formalin labeled "left lateral segment nodule", and consists of a 0.6 x 0.4 x 0.3 cm unoriented, red-gray to white, rubbery nodule that is bisected and entirely submitted in cassette 2A.

Signature Line

ACCESSION

Synoptic Report
HEPATOCELLULAR CARCINOMA: Hepatic Resection

Specimen:
Liver

Procedure:
Partial hepatectomy

Printed by:
Printed on:

[page 3 of 3]
SP Final Report

* Final Report *

Tumor Size:
Approximately 19.0 cm in greatest dimension

Tumor Focality:
Multiple

Histologic Type:
Hepatocellular carcinoma

Histologic Grade:
Moderate differentiated

Tumor Extension:
Tumor confined to liver

Margins:

Parenchymal Margin:
Involved by invasive carcinoma

Lymph-Vascular Invasion:
Not identified

Microscopic (Small Vessel) Invasion (L):
Not identified

*Perineural Invasion:
Not identified

Pathologic Staging (pTNM):
TNM Descriptors: _

Primary Tumor (pT):
pT3

Regional Lymph Nodes (pN):
pNx

Distant Metastasis (pM):
pMx

Printed by:
Printed on:

Page 3 of 3
(End of Report)

HPI/AA Discrepancy		✓

Source: NCI Genomic Data Commons file e3fe6b81-fc93-45d6-8405-150d372b96c5 (TCGA-RC-A6M4.EE8C11B9-C9E3-4940-86A0-08C388EB8C1A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).